Somatic mutation profile of tumor specimen TCGA-CD-A4MG-01A (aliquot TCGA-CD-A4MG-01A-11D-A25D-08) from TCGA case TCGA-CD-A4MG, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 76.7 years (28,019 days).
Specimen TCGA-CD-A4MG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4538b19-18e1-43a0-af3e-5481f7299748.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-A4MG-10A (Blood Derived Normal), aliquot TCGA-CD-A4MG-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd673744-249c-43aa-810b-47223ce608dc

The open-access MAF lists 2,703 somatic variants for this specimen: 2,075 protein-altering or splice-affecting, 578 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,400, Silent 578, Frame Shift Del 433, Frame Shift Ins 96, Nonsense Mutation 80, Intron 27, Splice Site 26, Splice Region 19, In Frame Del 17, RNA 8, 3'UTR 5, 5'Flank 5.

Variants (750 of 2,703; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- AGT | c.1290dup p.E431* | Frame Shift Ins (INS) | VAF 20/118 reads (17%) | catalogued as rs387906578; ClinVar: pathogenic; called by mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 36/137 reads (26%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BCL10 | c.499del p.S167Lfs*6 | Frame Shift Del (DEL) | VAF 40/94 reads (43%) | catalogued as rs387906350, COSV65354275; ClinVar: pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.2835del p.D946Ifs*14 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | catalogued as rs80359356, CM970180, COSV66450359; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CACNA1A | c.3423dup p.K1142Qfs*6 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | catalogued as rs746790849; ClinVar: pathogenic; called by mutect2, varscan2
- DYSF | c.4200dup p.I1401Hfs*8 | Frame Shift Ins (INS) | VAF 15/68 reads (22%) | catalogued as rs398123786; ClinVar: pathogenic; called by mutect2, varscan2
- EXT1 | c.247del p.R83Gfs*53 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | catalogued as rs1554601559, CD000256; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 28/50 reads (56%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- FBN1 | c.1868G>A p.C623Y | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1566914030, CM010883, COSV57331832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as rs80356517, CM040999, COSV55897351; ClinVar: pathogenic; called by muse, mutect2
- GLB1 | c.1577del p.G526Afs*74 | Frame Shift Del (DEL) | VAF 23/83 reads (28%) | catalogued as rs794729217; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HNF1B | c.1561del p.Q521Sfs*70 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- MFRP | chr11:119345562 ins G | 5'Flank (INS) | VAF 20/66 reads (30%) | catalogued as rs587776596; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 26/124 reads (21%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs63751113, CM021636, COSV52275309, COSV52291664; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4819dup p.Y1607Lfs*15 (on ENST00000358273 / NM_001042492.3; = p.Y1586Lfs*15 on NM_000267.3) | Frame Shift Ins (INS) | VAF 13/53 reads (25%) | catalogued as rs876658492; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.5609G>A p.R1870Q (on ENST00000358273 / NM_001042492.3; = p.R1849Q on NM_000267.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs786202112, CM1411401, CS000055, CS1311534, CS1311535, COSV62210316; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PEX1 | c.1927dup p.T643Nfs*21 | Frame Shift Ins (INS) | VAF 30/200 reads (15%) | catalogued as rs1554372180; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PLA2G6 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776713955, CM063032, COSV59273930; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RSPH4A | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as rs1034327724, COSV57633705; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.3994C>T p.P1332S (on ENST00000333535 / NM_198056.3; = p.P1331S on NM_000335.5) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794728877, COSV61131070; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B4 | c.1147del p.H383Mfs*75 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as rs387907186, CD123383; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SPG7 | c.1032del p.G345Afs*87 (on ENST00000268704; = p.G352Afs*87 on NM_003119.4) | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs760818649; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP63 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs121908849, CM013065, CM110083, COSV53200099; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VWA8 | c.4558C>T p.R1520* | Nonsense Mutation (SNP) | VAF 28/202 reads (14%) | catalogued as rs370112959; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.4154T>C p.M1385T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1377313968, COSV59392980; called by muse, mutect2, varscan2
- AARS2 | c.2763del p.K922Rfs*55 | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | catalogued as rs1372165915; called by mutect2, pindel, varscan2
- ABCA2 | c.6941C>T p.T2314M (on ENST00000614293; = p.T2284M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs767204092, COSV55807283; called by mutect2, varscan2
- ABCA2 | c.2375C>T p.S792F (on ENST00000614293; = p.S762F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs1425493830, COSV55807295, COSV99687575; called by muse, mutect2
- ABCA7 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.376); catalogued as COSV54033486, COSV54038027; called by muse, mutect2
- ABCB5 | c.2900C>T p.A967V (on ENST00000404938 / NM_001163941.2; = p.A522V on NM_178559.6) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV51722078; called by muse, mutect2, varscan2
- ABCB8 | c.187G>A p.V63M (on ENST00000297504 / NM_001282291.2; = p.V46M on NM_007188.5) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs566864336, COSV52502155; called by muse, mutect2, varscan2
- ABCB8 | c.2110G>A p.A704T (on ENST00000297504 / NM_001282291.2; = p.A687T on NM_007188.5) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs778555833, COSV52509320; called by muse, mutect2, varscan2
- ABCC8 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56858458; called by muse, mutect2, varscan2
- ABI2 | c.595C>T p.R199C (on ENST00000295851 / NM_001375719.1; = p.R193C on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV53696432; called by muse, mutect2, varscan2
- ABI3BP | c.1243del p.T415Lfs*96 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs768337403; called by mutect2, pindel, varscan2
- ABLIM3 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV58649166; called by muse, mutect2, varscan2
- ABT1 | c.265_267del p.K89del | In Frame Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs781785112; called by pindel, varscan2
- ABTB2 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100132158, COSV54396514; called by muse, mutect2, varscan2
- AC008676.3 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 70/166 reads (42%) | catalogued as rs1223084563, COSV56635806, COSV56636933; called by muse, mutect2, varscan2
- ACAA2 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53272430; called by muse, mutect2, varscan2
- ACACB | c.4630G>A p.A1544T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as rs374544605, COSV58145274; called by muse, mutect2, varscan2
- ACADM | c.270_271dup p.I91Tfs*18 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs766173642; called by mutect2, varscan2
- ACADSB | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1195273169, COSV62551537; called by muse, mutect2, varscan2
- ACAN | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as COSV61370320; called by muse, mutect2, varscan2
- ACAP3 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV61223774; called by muse, mutect2, varscan2
- ACCSL | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as rs754863482, COSV66583024; called by muse, mutect2, varscan2
- ACO2 | c.1556G>A p.G519D | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV53445762; called by muse, mutect2, varscan2
- ACOX1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV53137164; called by muse, mutect2, varscan2
- ACSM2A | c.353A>G p.E118G (on ENST00000219054; = p.E39G on NM_001308169.2) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54590392; called by muse, varscan2
- ACTL8 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs764213663, COSV64860202; called by muse, mutect2, varscan2
- ACTN2 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs730880041, COSV63973276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR5 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV54762355; called by muse, mutect2
- ACTRT2 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1292986662, COSV65758955; called by muse, mutect2, varscan2
- ACVR1B | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | catalogued as COSV57774850; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 44/74 reads (59%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM2 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV55869051; called by muse, mutect2
- ADAM21 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760644421, COSV50812714; called by muse, mutect2, varscan2
- ADAM21 | c.1486T>C p.C496R | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50812852; called by muse, mutect2, varscan2
- ADAMTS10 | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as COSV54359954; called by muse, mutect2, varscan2
- ADAMTS17 | c.1999G>A p.V667M | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748878355, COSV51495029; called by muse, mutect2, varscan2
- ADAMTS4 | c.1154G>A p.S385N | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV63488828; called by muse, mutect2, varscan2
- ADAMTS9 | c.681A>G p.E227= | Splice Region (SNP) | VAF 24/130 reads (18%) | catalogued as COSV55791720; called by muse, varscan2
- ADARB1 | c.2024G>A p.R675H (on ENST00000360697 / NM_001346687.2; = p.R635H on NM_001112.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs752123605, COSV62348616; called by muse, mutect2, varscan2
- ADCY4 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs753381771, COSV53474171; called by muse, mutect2, varscan2
- ADCY6 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1210399885, COSV57170882; called by muse, mutect2, varscan2
- ADCY6 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs763410189, COSV57168471; called by muse, mutect2, varscan2
- ADCY8 | c.3679C>T p.R1227W | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs753061333, COSV53930024; called by muse, varscan2
- ADCY9 | c.2779G>A p.V927M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs779548082, COSV53582340; called by muse, mutect2
- ADGRB3 | c.3935C>T p.P1312L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53261881; called by muse, mutect2, varscan2
- ADGRG4 | c.3720C>A p.H1240Q | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV54967758; called by muse, mutect2, varscan2
- ADH1C | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV72463700; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | catalogued as rs761350619; called by mutect2, varscan2
- ADPRH | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63695968; called by muse, mutect2, varscan2
- ADRA1A | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs528677959, COSV52356241; called by muse, mutect2, varscan2
- ADRB2 | c.887A>G p.H296R | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs369459230; called by muse, mutect2, varscan2
- AEBP1 | c.659A>G p.H220R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV56261626; called by muse, mutect2, varscan2
- AFF1 | c.1351C>G p.P451A | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); catalogued as COSV57124926; called by muse, mutect2, varscan2
- AFF1 | c.2758G>T p.G920W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57124936; called by muse, mutect2, varscan2
- AFF3 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV57875437; called by muse, varscan2
- AGAP2 | c.2243G>A p.G748D (on ENST00000547588 / NM_001122772.2; = p.G412D on NM_014770.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57732492; called by muse, mutect2, varscan2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 51/242 reads (21%) | catalogued as rs748399150; called by mutect2, varscan2
- AGPAT5 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs756652472, COSV53449451; called by muse, mutect2, varscan2
- AGR3 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1175122890, COSV60039585; called by muse, mutect2, varscan2
- AGRN | c.2096A>C p.E699A | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65072591; called by muse, mutect2, varscan2
- AGTRAP | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV58669642; called by muse, mutect2, varscan2
- AHCYL2 | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV61491573; called by muse, mutect2, varscan2
- AHSA1 | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV53633318; called by muse, mutect2, varscan2
- AIMP2 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52243649; called by muse, mutect2, varscan2
- AKAP13 | c.6059A>G p.Y2020C (on ENST00000394518 / NM_007200.5; = p.Y2024C on NM_006738.6) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63471056; called by mutect2, varscan2
- AKAP17A | c.430del p.E144Sfs*18 | Frame Shift Del (DEL) | VAF 68/264 reads (26%) | catalogued as COSV58308392; called by mutect2, pindel, varscan2
- ALDH1B1 | c.646del p.L216Sfs*20 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | catalogued as rs759954510; called by mutect2, pindel, varscan2
- ALDH3A1 | c.604A>G p.K202E | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV56737111; called by muse, mutect2, varscan2
- ALG10B | c.735A>C p.K245N | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV58145158; called by muse, mutect2
- ALK | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV66591328; called by muse, mutect2
- ALMS1 | c.11413C>T p.R3805* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as rs376091780, CM050173, COSV52519626; called by muse, mutect2, varscan2
- ALOX5 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs766026494, COSV65554794; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 45/191 reads (24%) | catalogued as rs1341338515; called by mutect2, varscan2
- ALPK2 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV64497658; called by muse, mutect2
- ALPK3 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as rs1418106287, COSV51940688; called by muse, mutect2, varscan2
- ALX4 | c.681G>T p.E227D | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV61329280; called by muse, mutect2, varscan2
- AMBRA1 | c.3859dup p.D1287Gfs*6 (on ENST00000458649 / NM_001367468.1; = p.D1197Gfs*6 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 22/108 reads (20%) | catalogued as rs1483640596; called by mutect2, pindel, varscan2
- AMBRA1 | c.1803G>T p.Q601H (on ENST00000458649 / NM_001367468.1; = p.Q511H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV54051684; called by muse, mutect2, varscan2
- AMDHD2 | c.629-1G>T p.X210_splice | Splice Site (SNP) | VAF 20/162 reads (12%) | catalogued as COSV53552570; called by muse, mutect2, varscan2
- AMOTL2 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs144219366; called by muse, mutect2
- AMPD2 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV56649149; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6838A>G p.T2280A | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as rs1412623958, COSV51856454, COSV51859644; called by muse, mutect2, varscan2
- ANKIB1 | c.2986A>G p.S996G | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV56066519; called by muse, mutect2, varscan2
- ANKRD1 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs760234190, COSV65468543; called by muse, mutect2, varscan2
- ANKRD11 | c.4681C>A p.P1561T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs750132258, COSV56373101; called by mutect2, varscan2
- ANKRD11 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56373115; called by muse, mutect2, varscan2
- ANKRD12 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV50852310; called by muse, mutect2, varscan2
- ANKRD2 | c.735+1G>A p.X245_splice | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV53969859; called by muse, mutect2, varscan2
- ANKRD50 | c.4114A>G p.N1372D | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.048); catalogued as COSV72386368; called by muse, mutect2, varscan2
- ANKRD6 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs369619069, COSV60237478; called by muse, mutect2, varscan2
- ANKRD6 | c.1151del p.P384Hfs*21 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs1293318031; called by pindel, varscan2
- ANKZF1 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768829938, COSV55479278; called by muse, mutect2, varscan2
- ANKZF1 | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0.096); catalogued as COSV55479282; called by muse, mutect2, varscan2
- ANPEP | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1408411355, COSV55595595; called by muse, mutect2, varscan2
- AOPEP | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52924346; called by muse, mutect2, varscan2
- AP1M1 | c.163del p.V55Sfs*182 | Frame Shift Del (DEL) | VAF 27/103 reads (26%) | catalogued as rs753324780, COSV52227333; called by mutect2, pindel, varscan2
- AP1S1 | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50802644; called by muse, varscan2
- APAF1 | c.1805dup p.N602Kfs*24 (on ENST00000551964 / NM_181861.2; = p.N591Kfs*24 on NM_001160.3) | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | catalogued as rs758129366; called by mutect2, varscan2
- APBB2 | c.1448A>G p.D483G (on ENST00000295974 / NM_001166050.2; = p.D484G on NM_004307.2) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55963743; called by muse, mutect2, varscan2
- APC | c.5161G>T p.G1721C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as COSV57386320; called by muse, mutect2, varscan2
- APCDD1L | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64487988; called by muse, mutect2, varscan2
- APEX2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374939146, COSV66624547; called by muse, varscan2
- APOB | c.10897T>C p.W3633R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51954725; called by muse, mutect2, varscan2
- APOB | c.9632del p.N3211Tfs*6 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as COSV99268025; called by pindel, varscan2
- APOB | c.2822C>G p.T941R | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.705); catalogued as COSV99268749; called by muse, mutect2, varscan2
- APOC4 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 107/325 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV52990721, COSV52991026; called by muse, mutect2, varscan2
- APOD | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV58402857; called by muse, mutect2
- APOE | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52986687; called by muse, mutect2, varscan2
- AQP9 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.669); catalogued as COSV54971259; called by muse, mutect2, varscan2
- AQR | c.895del p.S299Pfs*23 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as COSV50030271; called by mutect2, pindel, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARFGEF1 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV51617844; called by muse, mutect2, varscan2
- ARFGEF3 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52472011; called by muse, mutect2, varscan2
- ARHGAP1 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1169602059, COSV61239464; called by muse, mutect2, varscan2
- ARHGAP20 | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs73553992; called by muse, mutect2, varscan2
- ARHGAP20 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV52819956; called by muse, mutect2, varscan2
- ARHGEF12 | c.2597A>T p.E866V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV63107577; called by muse, mutect2
- ARHGEF12 | c.4153C>T p.R1385C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs750431916, COSV63107583; called by muse, mutect2, varscan2
- ARHGEF16 | c.1814+1G>A p.X605_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as rs374272150; called by mutect2, varscan2
- ARHGEF18 | c.808C>T p.R270C (on ENST00000359920 / NM_001130955.2; = p.R166C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs372921662, COSV60474630; called by muse, mutect2, varscan2
- ARID2 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.972); catalogued as rs186180564, COSV57615682; called by muse, mutect2, varscan2
- ARID2 | c.1547T>C p.V516A | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV57615691; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs776520069; called by mutect2, varscan2
- ARIH2 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.041); catalogued as rs778218697, COSV62703753; called by muse, mutect2, varscan2
- ARMCX2 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs1236877965, COSV57529313, COSV57531289; called by muse, mutect2, varscan2
- ARNT | c.1561A>G p.S521G | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV62232483; called by muse, mutect2, varscan2
- ARPP21 | c.2147T>C p.V716A | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV51809317; called by muse, mutect2, varscan2
- ASCC3 | c.6337G>A p.E2113K | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201205349, COSV64972258; called by muse, mutect2, varscan2
- ASGR1 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 39/250 reads (16%) | catalogued as COSV52649718; called by muse, mutect2, varscan2
- ASIC5 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV73332999; called by muse, mutect2
- ASPDH | c.808G>T p.A270S (on ENST00000389208 / NM_001114598.2; = p.A165S on NM_001024656.3) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as COSV65350922; called by muse, mutect2
- ASPM | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV54139676; called by muse, mutect2, varscan2
- ASPSCR1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs903138359, COSV60731446; called by muse, varscan2
- ASTN2 | c.2276G>A p.G759D (on ENST00000313400 / NM_001365069.1; = p.G708D on NM_014010.5) | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57820684; called by muse, mutect2, varscan2
- ASTN2 | c.445A>T p.M149L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as COSV57820706; called by mutect2, varscan2
- ATF2 | c.133C>A p.H45N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51376111; called by muse, varscan2
- ATF7IP | c.3470G>A p.S1157N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV53778650; called by muse, mutect2, varscan2
- ATG2A | c.4105G>A p.G1369S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs143404952; called by muse, mutect2, varscan2
- ATG2B | c.5947G>A p.A1983T | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV55892258; called by muse, mutect2, varscan2
- ATL2 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV60056775; called by muse, mutect2, varscan2
- ATP10A | c.3659G>A p.G1220D | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV63525477; called by muse, mutect2
- ATP10B | c.2275A>G p.S759G | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59165685; called by muse, mutect2, varscan2
- ATP11A | c.2888G>A p.R963H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs778847637, COSV52121868; called by mutect2, varscan2
- ATP1A4 | c.945del p.F315Lfs*38 | Frame Shift Del (DEL) | VAF 53/274 reads (19%) | catalogued as rs1218175053; called by mutect2, pindel, varscan2
- ATP1A4 | c.1756A>G p.M586V | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1425203841, COSV63628785; called by muse, mutect2, varscan2
- ATP2B4 | c.2063C>A p.A688D | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58184514; called by muse, mutect2, varscan2
- ATP2C1 | c.75del p.A26Qfs*21 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs1559936852, COSV60757077; called by mutect2, pindel, varscan2
- ATP4A | c.2042T>C p.L681P | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99383223; called by muse, mutect2, varscan2
- ATP4A | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV52872258; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1750C>A p.L584M | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); catalogued as COSV59481022; called by muse, mutect2, varscan2
- ATP6V0D1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1385784285, COSV52100085; called by muse, mutect2, varscan2
- ATP6V1B1 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599435; called by muse, mutect2, varscan2
- ATP7B | c.592A>G p.R198G | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); catalogued as CM164018, COSV54444891; called by muse, mutect2, varscan2
- ATRNL1 | c.2003A>G p.Y668C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.72); catalogued as COSV61818162; called by muse, mutect2
- ATRX | c.2567G>A p.S856N | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs782176247, COSV64884441; called by muse, mutect2
- ATXN7L3 | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV66989768; called by muse, mutect2, varscan2
- AURKB | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs866443565, COSV60244374; called by muse, mutect2
- AVPR1A | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as COSV54545978; called by muse, mutect2
- AZGP1 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as COSV52799702; called by muse, mutect2
- B3GALNT2 | c.1056G>C p.L352F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV64004653; called by muse, mutect2, varscan2
- B3GNT4 | c.242_243del p.T81Sfs*3 | Frame Shift Del (DEL) | VAF 66/307 reads (21%) | catalogued as rs757016083; called by pindel, varscan2
- BACE2 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs530813869, COSV57740272; called by muse, mutect2, varscan2
- BAG1 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.094); catalogued as COSV56304003; called by muse, mutect2, varscan2
- BARX1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751625001, COSV54159571; called by muse, mutect2, varscan2
- BCAM | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV54302412; called by muse, mutect2, varscan2
- BCAS3 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV66782995; called by muse, mutect2
- BCL6B | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.385); catalogued as rs546801346, COSV53428640; called by muse, mutect2, varscan2
- BCL9 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371893579; called by muse, mutect2, varscan2
- BCR | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.023); catalogued as COSV59936226; called by muse, mutect2
- BDKRB2 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs183204823, COSV60017248; called by mutect2, varscan2
- BDP1 | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62435229; called by muse, mutect2, varscan2
- BEND4 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV72469450; called by muse, varscan2
- BEND4 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV72469451; called by muse, varscan2
- BHLHA15 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52006303; called by muse, mutect2
- BLMH | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as rs755178186, COSV55587146; called by muse, mutect2, varscan2
- BLZF1 | c.962del p.K321Rfs*21 | Frame Shift Del (DEL) | VAF 29/108 reads (27%) | catalogued as rs1557849884; called by mutect2, pindel, varscan2
- BMF | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV55019692, COSV99590305; called by muse, mutect2, varscan2
- BMPR1A | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs55932635; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- BMPR2 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV65813754; called by muse, mutect2, varscan2
- BNC2 | c.2857A>G p.M953V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1343306709, COSV66177265; called by muse, mutect2, varscan2
- BOP1 | c.106del p.L36Sfs*154 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs782133829; called by mutect2, pindel
- BPNT1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs1050920488, COSV59041612; called by muse, mutect2, varscan2
- BRCA1 | c.5073A>C p.T1691= | Splice Region (SNP) | VAF 11/43 reads (26%) | catalogued as rs80356853, COSV58800975; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- BRINP2 | c.1844G>T p.R615M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV64180621; called by muse, mutect2, varscan2
- BRPF3 | c.2561del p.P854Rfs*6 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | catalogued as rs1413008697, COSV60208966; called by mutect2, pindel, varscan2
- BSG | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs747110729, COSV61076876, COSV61078309; called by muse, mutect2
- BTBD1 | c.1377del p.F459Lfs*12 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs1567100148; called by mutect2, pindel, varscan2
- BTBD11 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as rs1248310778, COSV55038874; called by muse, mutect2
- BTD | c.1004A>C p.D335A | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV57730747; called by muse, mutect2, varscan2
- BTG3 | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | catalogued as rs768550367; called by mutect2, varscan2
- C11orf54 | c.884T>C p.L295S (on ENST00000331239; = p.L245S on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs560795069, COSV58682492; called by muse, mutect2, varscan2
- C1QB | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV59246184; called by muse, mutect2
- C1S | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.062); catalogued as COSV61072465; called by muse, mutect2, varscan2
- C1orf105 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV62960019; called by muse, mutect2
- C20orf27 | c.37C>T p.R13W (on ENST00000379772 / NM_001258429.2; = p.R38W on NM_001039140.3) | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs781687163, COSV53925557; called by muse, mutect2, varscan2
- C22orf23 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs776578637, COSV50778083; called by muse, mutect2, varscan2
- C22orf42 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.198); catalogued as rs151297448; called by muse, varscan2
- C2CD2 | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV61600669; called by muse, mutect2, varscan2
- C2CD3 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs374283766, COSV58101845; called by muse, mutect2, varscan2
- C3AR1 | c.104del p.L35Yfs*16 | Frame Shift Del (DEL) | VAF 21/147 reads (14%) | catalogued as rs767570536; called by pindel, varscan2
- C3AR1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs371493019; called by muse, varscan2
- C4BPB | c.187del p.C63Afs*25 | Frame Shift Del (DEL) | VAF 33/94 reads (35%) | catalogued as rs1378141023; called by mutect2, pindel, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | catalogued as rs763603775; called by mutect2, pindel
- CA5A | c.91G>C p.G31R | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59243751; called by muse, mutect2, varscan2
- CACHD1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV51560532; called by mutect2, varscan2
- CACNA1A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV64201789; called by muse, mutect2, varscan2
- CACNA1D | c.2110G>T p.G704C (on ENST00000350061 / NM_001128840.3; = p.G724C on NM_000720.4) | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55466386; called by muse, mutect2, varscan2
- CACNA1E | c.4409G>A p.R1470H | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV62387568; called by muse, mutect2, varscan2
- CACNA1G | c.5459C>T p.T1820I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as COSV61740679; called by muse, mutect2, varscan2
- CACNA1G | c.6948del p.E2317Rfs*47 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | catalogued as rs766047428; called by mutect2, varscan2
- CACNB4 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.123); catalogued as COSV52399552, COSV52404565; called by mutect2, varscan2
- CACNG7 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV55817560; called by muse, varscan2
- CACNG8 | c.428del p.G143Vfs*29 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as COSV54415698, COSV99554878, COSV99555036; called by mutect2, pindel, varscan2
- CAD | c.5695G>A p.A1899T | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as rs770541452, COSV53032440; called by muse, mutect2, varscan2
- CADM3 | c.370G>A p.V124I (on ENST00000368125 / NM_001127173.3; = p.V158I on NM_021189.5) | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.767); catalogued as rs369946971, COSV63687640; called by muse, mutect2, varscan2
- CADM4 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs753225057, COSV55930050; called by muse, mutect2, varscan2
- CADPS2 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs1293595108, COSV57380135; called by muse, mutect2, varscan2
- CAND2 | c.2308C>A p.P770T (on ENST00000456430 / NM_001162499.2; = p.P677T on NM_012298.3) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as COSV55995178; called by muse, mutect2, varscan2
- CAPN12 | c.695T>G p.L232R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61018889; called by muse, mutect2, varscan2
- CARD11 | c.1663dup p.R555Pfs*38 | Frame Shift Ins (INS) | VAF 27/124 reads (22%) | catalogued as rs762770988; called by mutect2, varscan2
- CARMIL2 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV58032478; called by muse, mutect2, varscan2
- CARMIL3 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs989135022, COSV57728587; called by muse, mutect2
- CASP8 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51854284; called by muse, mutect2, varscan2
- CASP9 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775503596, COSV61602650; called by muse, mutect2, varscan2
- CASZ1 | c.4025C>A p.P1342H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.439); catalogued as COSV59741571; called by muse, mutect2, varscan2
- CATSPER1 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs755098505, COSV100376144, COSV56413780; called by mutect2, varscan2
- CATSPER1 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV56413791; called by muse, mutect2, varscan2
- CBFB | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs753519175, COSV52001926; called by muse, mutect2, varscan2
- CBLL2 | c.577del p.V193Cfs*25 | Frame Shift Del (DEL) | VAF 36/74 reads (49%) | catalogued as COSV60370814; called by mutect2, pindel, varscan2
- CBX4 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs768157778, COSV53967816; called by muse, mutect2, varscan2
- CCDC102A | c.1484G>T p.S495I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV50779901; called by muse, mutect2, varscan2
- CCDC138 | c.481T>G p.C161G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV54572319; called by muse, mutect2, varscan2
- CCDC142 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51780114; called by muse, mutect2, varscan2
- CCDC25 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV62958738; called by muse, mutect2, varscan2
- CCDC38 | c.1686del p.F562Lfs*4 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs769501825; called by mutect2, pindel, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC78 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs778696812, COSV53498175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC80 | c.632A>G p.E211G | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52820236; called by muse, mutect2, varscan2
- CCDC91 | c.841T>A p.S281T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.54); catalogued as COSV60349096; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCER1 | c.1096T>G p.S366A | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV62648858; called by muse, mutect2
- CCKBR | c.1271A>G p.D424G | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58106118; called by muse, mutect2, varscan2
- CCN5 | c.579del p.C194Afs*108 | Frame Shift Del (DEL) | VAF 51/140 reads (36%) | catalogued as COSV51937423; called by mutect2, pindel, varscan2
- CCT5 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 82/351 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs998269335, COSV54724191; called by muse, mutect2, varscan2
- CD2 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV65644945; called by muse, mutect2, varscan2
- CD96 | c.608A>G p.Q203R (on ENST00000283285 / NM_198196.3; = p.Q187R on NM_005816.5) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV51923757; called by muse, mutect2
- CDC20 | c.428-1G>A p.X143_splice | Splice Site (SNP) | VAF 15/280 reads (5%) | catalogued as COSV60523190; called by muse, mutect2
- CDC25A | c.1336A>T p.R446* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | catalogued as COSV56769745; called by muse, mutect2, varscan2
- CDC37 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55770105; called by muse, mutect2, varscan2
- CDC40 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV57012649; called by muse, mutect2, varscan2
- CDC42EP1 | c.289del p.R97Gfs*115 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as rs762035931; called by mutect2, pindel, varscan2
- CDH1 | c.1676G>A p.S559N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55741876; called by muse, mutect2, varscan2
- CDH10 | c.1655dup p.N552Kfs*5 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | catalogued as rs754722288; called by mutect2, pindel, varscan2
- CDH18 | c.2179C>A p.P727T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV56964420; called by muse, mutect2, varscan2
- CDH2 | c.1808C>A p.P603H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52272660; called by muse, mutect2, varscan2
- CDH23 | c.5150G>T p.C1717F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV99824576; called by muse, mutect2, varscan2
- CDH26 | c.1085G>T p.R362M | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV54845073, COSV54856215; called by muse, mutect2, varscan2
- CDK19 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV60453991; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2882T>C p.V961A | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.035); catalogued as COSV62577971; called by muse, mutect2, varscan2
- CDKL4 | c.593A>C p.Q198P | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV66511202; called by muse, mutect2
- CDKN1A | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV55191839, COSV99781282; called by muse, mutect2, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs759091263; called by mutect2, varscan2
- CDT1 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs146872515, COSV56348396; called by muse, mutect2, varscan2
- CEACAM1 | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV50733770; called by muse, varscan2
- CEACAM1 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV50733826; called by muse, mutect2, varscan2
- CEACAM3 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV55763407; called by muse, mutect2, varscan2
- CELF4 | c.1361G>A p.S454N | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58467427; called by muse, mutect2, varscan2
- CELSR1 | c.6343A>G p.M2115V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs770797108, COSV99420605; called by muse, mutect2, varscan2
- CELSR3 | c.8119A>G p.T2707A | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV51163191; called by muse, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CENPF | c.6135G>T p.Q2045H | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as COSV65279506; called by muse, mutect2, varscan2
- CENPU | c.48C>T p.G16= | Splice Region (SNP) | VAF 6/26 reads (23%) | catalogued as rs374369387; called by muse, mutect2, varscan2
- CEP128 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV53678786; called by muse, mutect2, varscan2
- CEP152 | c.4027G>A p.A1343T (on ENST00000380950 / NM_001194998.2; = p.A1287T on NM_014985.4) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV57865398; called by muse, mutect2
- CEP162 | c.3292A>G p.K1098E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100003560; called by muse, varscan2
- CEP162 | c.3247G>A p.A1083T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV57625127; called by muse, varscan2
- CEP164 | c.2857C>T p.R953W | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs767099855, COSV54046819; called by muse, mutect2, varscan2
- CEP250 | c.3247A>G p.S1083G | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV61174955; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CETP | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as rs142750310, CM062501; called by mutect2, varscan2
- CFAP44 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as rs759624707, COSV55616186; called by muse, mutect2, varscan2
- CFAP45 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751910284, COSV63651302; called by muse, mutect2, varscan2
- CFAP46 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs191258313, COSV63955291; called by muse, mutect2, varscan2
- CFAP54 | c.5885G>A p.G1962D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.125); catalogued as rs1199241795, COSV61572414; called by muse, mutect2, varscan2
- CGGBP1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100532097, COSV58853150; called by muse, mutect2, varscan2
- CHDH | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267599903, COSV55466405; called by muse, mutect2, varscan2
- CHM | c.709T>C p.Y237H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63304972; called by muse, mutect2, varscan2
- CHMP3 | c.408+2T>C p.X136_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | catalogued as COSV55688132; called by muse, mutect2, varscan2
- CHPF2 | c.1941del p.S648Pfs*13 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs746469175; called by mutect2, pindel, varscan2
- CHPF2 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.891); catalogued as rs138308089, COSV99223451; called by muse, mutect2, varscan2
- CHRNE | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV53420351; called by mutect2, varscan2
- CHST2 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58887199; called by muse, mutect2, varscan2
- CIAO3 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52405181; called by muse, mutect2, varscan2
- CLCA2 | c.2615A>G p.N872S | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV65288936; called by muse, mutect2, varscan2
- CLDN22 | c.311G>A p.C104Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs759631498, COSV60109906; called by muse, mutect2, varscan2
- CLEC18C | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.041); catalogued as rs759746304, COSV100032187; called by mutect2, varscan2
- CLN6 | c.900G>T p.W300C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV51118385; called by muse, mutect2, varscan2
- CLSTN2 | c.2078A>G p.N693S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); catalogued as rs756126789, COSV71725498; called by muse, mutect2, varscan2
- CLU | c.1283C>A p.P428H | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57068567; called by muse, varscan2
- CLU | c.1166T>C p.V389A | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV57068579; called by muse, varscan2
- CLUH | c.1324del p.D442Tfs*12 (on ENST00000435359; = p.D480Tfs*12 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | catalogued as rs752224729; called by pindel, varscan2
- CLUH | c.1267A>G p.N423D (on ENST00000435359; = p.N461D on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70930176; called by muse, varscan2
- CNDP1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs371268412; called by muse, mutect2, varscan2
- CNGA1 | c.841T>A p.F281I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV62057220; called by muse, mutect2, varscan2
- CNGB1 | c.3747G>T p.K1249N | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.264); catalogued as COSV51907725; called by muse, mutect2
- CNN3 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54734268; called by muse, mutect2, varscan2
- CNOT1 | c.2072T>C p.V691A | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV57781380; called by muse, mutect2
- CNOT4 | c.1937G>T p.G646V (on ENST00000541284 / NM_001190850.1; = p.G572V on NM_013316.4) | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.031); catalogued as COSV64160620; called by muse, mutect2, varscan2
- CNR1 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs764560714, COSV62986478; called by muse, mutect2, varscan2
- CNTN3 | c.1756G>T p.V586F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55185583; called by muse, mutect2, varscan2
- CNTN3 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.857); catalogued as rs752936529, COSV55176589; called by mutect2, varscan2
- CNTNAP5 | c.3554T>C p.V1185A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV70514263; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 19/33 reads (58%) | catalogued as rs374805044; called by mutect2, varscan2
- COG6 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1268992012, COSV62995500, COSV62995628; called by muse, mutect2
- COL11A2 | c.3833dup p.G1279Wfs*12 (on ENST00000341947 / NM_080680.3; = p.G1172Wfs*12 on NM_080679.2) | Frame Shift Ins (INS) | VAF 26/111 reads (23%) | catalogued as rs1259037195; called by mutect2, pindel, varscan2
- COL12A1 | c.4924del p.E1642Sfs*5 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as COSV59390565; called by mutect2, pindel, varscan2
- COL13A1 | c.1029G>T p.K343N (on ENST00000398978 / NM_001130103.2; = p.K286N on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV62570572, COSV62575813; called by muse, mutect2, varscan2
- COL1A1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758897245, COSV56802381; called by muse, mutect2, varscan2
- COL20A1 | c.3517G>A p.V1173M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs370233069; called by muse, mutect2, varscan2
- COL24A1 | c.4675A>C p.K1559Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.392); catalogued as COSV65315041; called by muse, mutect2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 8/36 reads (22%) | catalogued as rs760493024; called by mutect2, varscan2
- COL2A1 | c.2950G>T p.G984C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD070453, CM160213, COSV61534882; called by muse, mutect2, varscan2
- COL4A1 | c.2266del p.E756Rfs*46 | Frame Shift Del (DEL) | VAF 28/179 reads (16%) | catalogued as COSV65430452; called by mutect2, pindel, varscan2
- COL4A1 | c.1943del p.P648Lfs*154 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as COSV101011622; called by mutect2, pindel, varscan2
- COL4A3 | c.3058A>G p.M1020V | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV59259676; called by muse, mutect2, varscan2
- COL4A4 | c.2860G>T p.G954* | Nonsense Mutation (SNP) | VAF 40/63 reads (63%) | catalogued as COSV61637141; called by muse, mutect2, varscan2
- COL4A5 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV60367533, COSV60373083; called by muse, mutect2, varscan2
- COL4A5 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60373101; called by muse, mutect2, varscan2
- COL4A5 | c.4798A>G p.M1600V | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as rs760241969, COSV100090669; called by muse, mutect2, varscan2
- COL5A2 | c.3802G>A p.V1268I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV66415881; called by muse, mutect2, varscan2
- COL6A2 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV56017197; called by muse, mutect2, varscan2
- COL8A1 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs1226770157, COSV53738510; called by muse, mutect2, varscan2
- COL9A3 | c.369dup p.G124Rfs*44 | Frame Shift Ins (INS) | VAF 27/87 reads (31%) | catalogued as rs1218220070; called by mutect2, pindel, varscan2
- COMMD8 | c.278G>A p.C93Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67500804; called by muse, mutect2, varscan2
- COPB2 | c.1958A>G p.E653G | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV60813975; called by muse, mutect2, varscan2
- CORO7 | c.1337C>A p.P446H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52034455; called by muse, mutect2, varscan2
- CPA2 | c.946T>C p.Y316H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756153369, COSV55981564; called by muse, mutect2, varscan2
- CPD | c.2800C>A p.H934N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV56716709; called by muse, varscan2
- CPEB1 | c.1419A>C p.L473F (on ENST00000617958; = p.L408F on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV55621901; called by muse, mutect2, varscan2
- CPEB2 | c.1447G>T p.G483C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as COSV52595942; called by muse, mutect2, varscan2
- CPEB4 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.031); catalogued as rs760479707, COSV54176611; called by mutect2, varscan2
- CPED1 | c.933del p.F311Lfs*5 | Frame Shift Del (DEL) | VAF 21/116 reads (18%) | catalogued as rs1361659782; called by mutect2, pindel, varscan2
- CPNE9 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as rs1020442573, COSV56007917; called by muse, mutect2, varscan2
- CPT1B | c.154_155insT p.R52Mfs*89 | Frame Shift Ins (INS) | VAF 5/54 reads (9%) | catalogued as COSV100376910; called by mutect2, pindel
- CREBBP | c.3893A>G p.Y1298C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); catalogued as rs773159964, COSV52125779; called by muse, mutect2, varscan2
- CREBBP | c.3836C>T p.P1279L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.997); catalogued as rs749189606, COSV52142574; called by muse, mutect2, varscan2
- CREBBP | c.2506C>A p.L836M | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.93); catalogued as COSV52142586; called by muse, mutect2, varscan2
- CREBBP | c.2279C>A p.P760Q | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.973); catalogued as COSV52142594; called by muse, mutect2
- CRIP1 | c.182T>C p.F61S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57636275; called by muse, mutect2, varscan2
- CRNN | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 213/475 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.248); catalogued as COSV55124097; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CRYZ | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs775718634, COSV61716812, COSV61718731; called by muse, mutect2, varscan2
- CSF1R | c.2897C>T p.P966L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV53844051; called by muse, mutect2, varscan2
- CSF3R | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV58965340; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1454G>A p.W485* | Nonsense Mutation (SNP) | VAF 37/157 reads (24%) | catalogued as COSV65678454; called by muse, mutect2, varscan2
- CSMD1 | c.5452G>A p.G1818S (on ENST00000520002; = p.G1817S on NM_033225.6) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769067339, COSV59281721; called by muse, mutect2, varscan2
- CSNK1A1L | c.183C>A p.S61R | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as rs1205241740, COSV65790346; called by muse, mutect2, varscan2
- CSNK1G2 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55337437; called by muse, mutect2, varscan2
- CSPP1 | c.907G>A p.A303T (on ENST00000676605; = p.A262T on NM_024790.6) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.03); catalogued as rs771943937, COSV51593305; called by muse, mutect2, varscan2
- CSTF1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs762176502, COSV53858360; called by muse, mutect2, varscan2
- CTBP2 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58338474; called by muse, mutect2, varscan2
- CTNND2 | c.1117A>G p.S373G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58931686; called by muse, mutect2, varscan2
- CTSW | c.1066A>G p.K356E | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV57173354; called by muse, mutect2
- CTTNBP2 | c.660C>G p.S220R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as COSV50486062; called by muse, mutect2, varscan2
- CTTNBP2 | c.343A>G p.M115V | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV50486386; called by muse, mutect2, varscan2
- CUBN | c.466del p.C156Vfs*27 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs755846379; called by mutect2, pindel, varscan2
- CUL4A | c.1400C>T p.A467V (on ENST00000375440 / NM_001008895.4; = p.A367V on NM_003589.3) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV58376378; called by mutect2, varscan2
- CUL7 | c.3430A>G p.T1144A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.456); catalogued as COSV54822526; called by muse, mutect2, varscan2
- CUL9 | c.2245G>A p.V749M | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs376469889; called by muse, mutect2, varscan2
- CUL9 | c.5101T>C p.S1701P | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52735455; called by muse, mutect2, varscan2
- CWF19L1 | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs756068263, COSV62499861; called by muse, mutect2, varscan2
- CYB5R1 | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 70/386 reads (18%) | catalogued as COSV65917403; called by muse, mutect2, varscan2
- CYBC1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as rs1192858254, COSV60066301; called by muse, mutect2, varscan2
- CYP27A1 | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs1390340364, COSV51470397; called by muse, mutect2, varscan2
- CYP4V2 | c.571del p.Y191Tfs*7 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs1467050790; called by mutect2, pindel
- CYTH2 | c.1201T>C p.*401Rext*45 (on ENST00000427476; = p.*400Rext*45 on NM_004228.7) | Nonstop Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as COSV57310925; called by muse, mutect2
- CYTIP | c.730A>C p.S244R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs748002457, COSV51636399; called by muse, mutect2, varscan2
- DAAM2 | c.1714C>A p.P572T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV51421039; called by muse, mutect2
- DACT1 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868334123, COSV60019297; called by muse, mutect2, varscan2
- DAG1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.097); catalogued as COSV58187486; called by muse, mutect2, varscan2
- DAG1 | c.1685A>G p.Y562C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761497544, COSV58187498; called by muse, mutect2, varscan2
- DAGLA | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57200454; called by muse, mutect2, varscan2
- DAPK1 | c.3822dup p.Y1275Vfs*64 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | catalogued as rs779681511; called by mutect2, varscan2
- DCAF12L2 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs776346189, COSV63582048; called by muse, mutect2, varscan2
- DCAF4L2 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60480562, COSV60481042; called by muse, mutect2, varscan2
- DCLK1 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55174019; called by muse, mutect2, varscan2
- DCLRE1C | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63185745; called by muse, mutect2, varscan2
- DCN | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778750338, COSV50006318; called by muse, mutect2, varscan2
- DCN | c.430T>A p.L144M | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as COSV50009602; called by muse, mutect2, varscan2
- DCP1B | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54972714; called by muse, mutect2, varscan2
- DCST1 | c.1408C>G p.L470V | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as rs202162660, COSV55063674; called by muse, varscan2
- DCTN1 | c.2508G>T p.W836C | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV62621623; called by muse, mutect2, varscan2
- DCUN1D2 | c.587G>T p.W196L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60262902; called by mutect2, varscan2
- DDB1 | c.1069G>T p.G357* | Nonsense Mutation (SNP) | VAF 9/109 reads (8%) | catalogued as COSV57106128; called by muse, mutect2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX31 | c.2297C>A p.A766E | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.113); catalogued as COSV100936825, COSV64651791; called by muse, mutect2, varscan2
- DDX31 | c.1559G>A p.C520Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV60139993; called by muse, mutect2, varscan2
- DDX31 | c.1513T>G p.C505G | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV60137212; called by muse, mutect2, varscan2
- DDX4 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV61757618; called by muse, mutect2, varscan2
- DDX50 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV65293450; called by muse, mutect2, varscan2
- DECR1 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV55170846, COSV55170914; called by muse, mutect2, varscan2
- DEFB1 | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52413488; called by muse, mutect2, varscan2
- DENND2A | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 57/228 reads (25%) | catalogued as rs372731585; called by muse, mutect2, varscan2
- DENND3 | c.1502G>A p.G501D | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.058); catalogued as COSV52807438; called by muse, mutect2
- DENND4A | c.3118A>C p.M1040L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV71267102; called by muse, mutect2, varscan2
- DENND4A | c.2648A>G p.Q883R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as COSV71265616, COSV71267104; called by muse, mutect2, varscan2
- DEPDC1 | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 27/162 reads (17%) | catalogued as COSV63959422; called by muse, mutect2, varscan2
- DEPDC5 | c.3248C>T p.A1083V (on ENST00000400246; = p.A1152V on NM_014662.5) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV56711921; called by muse, mutect2, varscan2
- DGCR8 | c.2232G>T p.E744D | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV52815206; called by muse, mutect2, varscan2
- DGKB | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751382500, COSV51765781, COSV51780055; called by mutect2, varscan2
- DHX29 | c.1066G>T p.D356Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV52422736; called by muse, mutect2
- DHX30 | c.2110+1G>A p.X704_splice (on ENST00000445061 / NM_138615.3; = p.X665_splice on NM_014966.3) | Splice Site (SNP) | VAF 3/16 reads (19%) | catalogued as COSV53143341; called by muse, mutect2
- DICER1 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.081); catalogued as rs1181141404, COSV58629011, COSV58629566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIDO1 | c.4430A>C p.K1477T | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV56634825; called by muse, mutect2, varscan2
- DIPK1B | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs549609567, COSV63037959; called by muse, mutect2, varscan2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLEC1 | c.3733C>A p.L1245M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.735); catalogued as COSV57307406; called by muse, mutect2, varscan2
- DLG1 | c.2408G>A p.G803D (on ENST00000419354 / NM_001290983.1; = p.G825D on NM_004087.2) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58392313; called by muse, mutect2, varscan2
- DLGAP2 | c.393del p.R132Afs*15 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs755665055, COSV101422687, COSV70099967; called by mutect2, pindel, varscan2
- DLGAP4 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV59424082; called by muse, varscan2
- DMKN | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60090343; called by muse, mutect2, varscan2
- DMPK | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs745965249, COSV52182738; called by muse, mutect2, varscan2
- DMXL1 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV60722006; called by mutect2, varscan2
- DNAAF5 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs760388668, COSV52421988; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.7322G>A p.R2441K | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70237051; called by muse, mutect2, varscan2
- DNAH11 | c.8242G>T p.D2748Y | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60984458; called by muse, mutect2, varscan2
- DNAH2 | c.212A>T p.E71V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV50021367; called by muse, mutect2, varscan2
- DNAH2 | c.2714_2715del p.S905Cfs*7 | Frame Shift Del (DEL) | VAF 70/328 reads (21%) | catalogued as rs766303944; called by pindel, varscan2
- DNAH2 | c.9703G>A p.A3235T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as rs771215997, COSV66728080; called by muse, mutect2, varscan2
- DNAH3 | c.12169G>A p.A4057T | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.269); catalogued as rs369704821; called by muse, mutect2, varscan2
- DNAH8 | c.5714T>C p.L1905S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776821810, COSV59483718; called by muse, mutect2, varscan2
- DNAJC13 | c.4636T>C p.Y1546H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53459069; called by muse, mutect2, varscan2
- DNAJC2 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.123); catalogued as COSV50795083; called by muse, mutect2, varscan2
- DNASE2 | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52246262; called by muse, varscan2
- DNHD1 | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 31/144 reads (22%) | catalogued as rs1289549552, COSV54443925; called by muse, mutect2, varscan2
- DNPEP | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 78/135 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs763581929, COSV56112065; called by muse, varscan2
- DNTTIP2 | c.713A>G p.D238G | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); catalogued as COSV63284687; called by muse, mutect2, varscan2
- DOCK2 | c.5294C>T p.A1765V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs141274816; ClinVar: uncertain significance; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.5429C>T p.S1810L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1185157154, COSV70243767; called by muse, mutect2, varscan2
- DOCK7 | c.4081G>A p.D1361N (on ENST00000635253 / NM_001367561.1; = p.D1330N on NM_033407.3) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV52022700; called by muse, mutect2, varscan2
- DOCK7 | c.569G>A p.S190N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs747518912, COSV52022722; called by muse, mutect2, varscan2
- DOT1L | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67113749; called by muse, mutect2
- DPAGT1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as COSV62615263; called by muse, mutect2, varscan2
- DPP4 | c.2206A>G p.T736A | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs1340660444, COSV62106320; called by muse, varscan2
- DRAM1 | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.576); catalogued as COSV51600652; called by muse, mutect2, varscan2
- DRD2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1487691738, COSV60758953; called by muse, mutect2
- DRD4 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV51563511; called by muse, mutect2
- DSCC1 | c.524G>C p.S175T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58088541; called by mutect2, varscan2
- DSP | c.7103T>C p.L2368S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65796458; called by muse, mutect2, varscan2
- DTX1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57501899; called by muse, varscan2
- DTX1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.989); catalogued as COSV57501912; called by muse, varscan2
- DUSP4 | c.97A>G p.S33G | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.035); catalogued as COSV53548009; called by muse, mutect2, varscan2
- DYNC1I1 | c.242del p.L81* | Frame Shift Del (DEL) | VAF 19/121 reads (16%) | catalogued as rs781167095; called by mutect2, pindel, varscan2
- DYNC1LI1 | c.201del p.K68Rfs*16 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as COSV56128829; called by mutect2, pindel
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as rs751377941; called by mutect2, varscan2
- DYRK1B | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV59915557; called by muse, mutect2, varscan2
- EAF1 | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as COSV67542670; called by muse, mutect2, varscan2
- ECEL1 | c.590dup p.R199Afs*66 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as COSV58811138; called by mutect2, pindel, varscan2
- EDEM1 | c.1325del p.F442Sfs*7 | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | catalogued as rs1261991799, COSV56581918; called by mutect2, pindel, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs769735757; ClinVar: risk factor; called by pindel, varscan2
- EDNRB | c.984A>G p.I328M (on ENST00000377211 / NM_001201397.1; = p.I238M on NM_000115.5) | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV57528514; called by muse, mutect2, varscan2
- EFCAB5 | c.2207del p.K736Rfs*16 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs755823613; called by mutect2, pindel, varscan2
- EFEMP2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.197); catalogued as rs776088168, COSV57261646; called by muse, mutect2, varscan2
- EFTUD2 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68185070; called by muse, mutect2, varscan2
- EGFR | c.1289C>T p.T430I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.282); catalogued as COSV51852047; called by muse, mutect2, varscan2
- EGR4 | c.884C>T p.S295L (on ENST00000545030; = p.S192L on NM_001965.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV71532332; called by muse, mutect2, varscan2
- EHD3 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV59033202; called by muse, mutect2
- EHHADH | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs748785259, COSV51633819; called by muse, mutect2, varscan2
- EIF3A | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV64963667; called by muse, varscan2
- EIF4E3 | c.345-2A>C p.X115_splice (on ENST00000425534 / NM_001134651.2; = p.X9_splice on NM_173359.5) | Splice Site (SNP) | VAF 12/73 reads (16%) | catalogued as COSV55207268; called by muse, mutect2, varscan2
- ELMO1 | c.1823T>G p.L608R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV60327035; called by muse, mutect2, varscan2
- ELOA2 | c.1907G>A p.G636D | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.598); catalogued as COSV55309552; called by muse, mutect2
- ELP6 | c.39del p.D14Tfs*8 | Frame Shift Del (DEL) | VAF 17/77 reads (22%) | catalogued as rs1395402715; called by mutect2, pindel, varscan2
- EMILIN1 | c.1353dup p.L452Afs*57 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | catalogued as rs763633527; called by mutect2, varscan2
- EMILIN1 | c.2240T>C p.L747P | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53157643; called by muse, varscan2
- ENPP2 | c.1307C>T p.A436V (on ENST00000075322 / NM_001040092.3; = p.A488V on NM_006209.5) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as COSV50042290; called by muse, mutect2, varscan2
- EPB41L5 | c.1093A>G p.T365A | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55358467; called by muse, mutect2, varscan2
- EPC1 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs749963073, COSV53930105; called by muse, mutect2, varscan2
- EPHA2 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64454903; called by muse, mutect2, varscan2
- EPHA4 | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56045181; called by muse, mutect2, varscan2
- EPHB1 | c.245C>G p.A82G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV67672695; called by muse, mutect2, varscan2
- EPHB6 | c.165+1del | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | catalogued as rs771807343; called by mutect2, pindel, varscan2
- EPHB6 | c.1475T>C p.V492A | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1401805543, COSV63893917; called by muse, mutect2, varscan2
- EPHX1 | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV55304357; called by muse, varscan2
- EPPK1 | c.4607C>T p.A1536V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs782364262, COSV73262432, COSV73262441; called by muse, mutect2
- EPSTI1 | c.466del p.M156* | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs781504180; called by mutect2, pindel, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 12/30 reads (40%) | catalogued as rs768793415; called by mutect2, varscan2
- ERBB4 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs372631205; called by muse, mutect2, varscan2
- ERC1 | c.2449C>T p.R817W (on ENST00000360905 / NM_178040.4; = p.R789W on NM_178039.4) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370753733; called by muse, mutect2, varscan2
- ERCC4 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145402255, CM1313088, COSV61312077; called by muse, mutect2, varscan2
- ESRP1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64412439; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | catalogued as rs775950025; called by mutect2, varscan2
- ESYT1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV57276743; called by muse, mutect2, varscan2
- ETS1 | c.1007A>G p.Q336R | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV60098173; called by muse, mutect2, varscan2
- ETS1 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as rs766964257, COSV60092018; called by muse, mutect2, varscan2
- EVC2 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV60403810; called by muse, mutect2, varscan2
- EVPL | c.4237C>T p.R1413W | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1038019114, COSV56916360; called by muse, mutect2, varscan2
- F13B | c.115T>C p.Y39H | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66375888; called by muse, mutect2, varscan2
- F2RL3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs527989109, COSV50186773; called by muse, mutect2, varscan2
- F5 | c.3183A>C p.E1061D | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63128946; called by muse, mutect2
- FAAH2 | c.98del p.G33Vfs*12 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as COSV100887477; called by mutect2, varscan2
- FAM114A2 | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV59457606; called by muse, mutect2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM135A | c.3559A>G p.N1187D (on ENST00000370479 / NM_001351599.1; = p.N974D on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as COSV52060200; called by muse, mutect2
- FAM135B | c.2408G>A p.S803N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV52716667, COSV52755853; called by muse, mutect2, varscan2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 19/59 reads (32%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM155B | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as COSV52938005; called by muse, mutect2, varscan2
- FAM171A1 | c.2078T>C p.L693P | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65320556; called by muse, mutect2, varscan2
- FAM184A | c.2447C>A p.A816D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58853402; called by muse, mutect2, varscan2
- FAM186B | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs758246506, COSV57723292; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs746881923; called by pindel, varscan2
- FAM219A | c.526G>A p.A176T (on ENST00000445726; = p.A159T on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV52622801; called by muse, varscan2
- FAM222A | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62724134; called by muse, mutect2, varscan2
- FAM47C | c.2003del p.P668Rfs*157 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | catalogued as COSV63729354; called by pindel, varscan2
- FAM53C | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV53513132; called by muse, mutect2, varscan2
- FAM83E | c.1100dup p.A368Gfs*21 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | catalogued as rs748927204; called by mutect2, pindel, varscan2
- FAM83H | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV66354740; called by muse, mutect2, varscan2
- FAM91A1 | c.257T>C p.M86T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs767545105, COSV58240092; called by mutect2, varscan2
- FAR2 | c.638T>G p.M213R | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV51730116; called by muse, mutect2, varscan2
- FASN | c.7522G>A p.V2508M | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV60761764; called by muse, mutect2
- FASN | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60761784; called by muse, mutect2, varscan2
- FAT1 | c.6740A>G p.H2247R | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as COSV71676190; called by muse, mutect2, varscan2
- FAT1 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs536104649, COSV71674334; called by muse, mutect2, varscan2
- FAT2 | c.12132G>T p.W4044C | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as COSV55830412; called by muse, mutect2, varscan2
- FAT3 | c.2143T>G p.F715V | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV53112635, COSV53165730; called by muse, mutect2
- FAT3 | c.2323A>G p.N775D | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.215); catalogued as rs1455202526, COSV53179582; called by muse, mutect2, varscan2
- FAT4 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV67901550; called by muse, varscan2
- FAT4 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV67901556; called by muse, varscan2
- FAT4 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67901558; called by muse, mutect2, varscan2
- FBN3 | c.5969G>T p.G1990V | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54474243; called by muse, mutect2, varscan2
- FBN3 | c.3146G>A p.G1049D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54474249; called by muse, mutect2, varscan2
- FBN3 | c.1803del p.L602Wfs*3 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as rs772353703; called by mutect2, pindel, varscan2
- FBXL18 | c.1055G>A p.G352D | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1343200569, COSV66668877; called by muse, mutect2, varscan2
- FBXL7 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV61648269; called by muse, mutect2, varscan2
- FBXO10 | c.2560G>A p.V854M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as rs771016576, COSV52835953; called by muse, mutect2, varscan2
- FBXO11 | c.1583T>C p.V528A (on ENST00000403359 / NM_001190274.2; = p.V444A on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV57026874; called by muse, mutect2, varscan2
- FBXO16 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV60777926; called by muse, mutect2, varscan2
- FBXO28 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV64801609; called by muse, mutect2
- FCGBP | c.5446G>A p.G1816S | Missense Mutation (SNP) | VAF 65/336 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440002489; called by muse, mutect2, varscan2
- FCN3 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as rs775014167, COSV54641787; called by muse, mutect2, varscan2
- FDFT1 | c.381+1G>A p.X127_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV55044122; called by muse, mutect2, varscan2
- FES | c.2083A>C p.N695H | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV61001687; called by muse, mutect2, varscan2
- FGA | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57401736; called by muse, mutect2, varscan2
- FGD4 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1131691854, COSV56789953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGF9 | c.132del p.L45Sfs*13 | Frame Shift Del (DEL) | VAF 18/129 reads (14%) | catalogued as COSV101211034; called by mutect2, pindel, varscan2
- FGFR4 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs766591955, COSV52810523; called by muse, mutect2, varscan2
- FHL2 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59080661; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIG4 | c.1363T>C p.C455R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as rs1012991465, COSV57791824; called by muse, mutect2, varscan2
- FIGN | c.799dup p.A267Gfs*100 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | catalogued as rs755527396; called by mutect2, varscan2
- FIGNL1 | c.372del p.K124Nfs*15 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | catalogued as COSV63554218; called by mutect2, pindel, varscan2
- FKBP11 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV56740406; called by muse, mutect2
- FLG | c.2227A>G p.S743G | Missense Mutation (SNP) | VAF 180/804 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV64250661; called by muse, varscan2
- FLII | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV58948425; called by muse, mutect2, varscan2
- FLNA | c.2257A>G p.S753G | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV61052629; called by muse, mutect2, varscan2
- FLNA | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs782425251, COSV61040280; called by muse, mutect2, varscan2
- FLNB | c.2737A>G p.T913A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV55897371; called by muse, mutect2, varscan2
- FLYWCH1 | c.1879G>C p.V627L (on ENST00000253928 / NM_001308068.2; = p.V626L on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV54150117; called by muse, mutect2, varscan2
- FMNL3 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV53302674; called by muse, mutect2, varscan2
- FNDC3A | c.1943C>T p.A648V (on ENST00000492622 / NM_001079673.2; = p.A592V on NM_014923.5) | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs1183680891, COSV68132428; called by muse, mutect2
- FOXA2 | c.232G>T p.A78S (on ENST00000377115 / NM_153675.3; = p.A84S on NM_021784.5) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV65797180; called by muse, mutect2, varscan2
- FOXN2 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs767260719, COSV61320055; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FPGS | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1170943148, COSV64676307; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | catalogued as rs752538869; called by mutect2, pindel
- FRMD5 | c.1409C>T p.T470I | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV68725810; called by muse, mutect2, varscan2
- FRZB | c.383A>G p.H128R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV54556292; called by muse, mutect2, varscan2
- FSIP1 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV63227222; called by muse, varscan2
- FTSJ3 | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV63791538; called by muse, mutect2, varscan2
- FZD8 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV65968565; called by muse, mutect2, varscan2
- GABRG1 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV54962553; called by muse, mutect2, varscan2
- GABRQ | c.1323G>T p.Q441H | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.562); catalogued as COSV64784124; called by muse, mutect2, varscan2
- GABRR2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs374158881; called by muse, mutect2, varscan2
- GALNT15 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs145410737, COSV60216763; called by mutect2, varscan2
- GALNT18 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as COSV57158779; called by muse, mutect2
- GALNT6 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373677203, COSV100695410; called by muse, mutect2, varscan2
- GAN | c.493A>G p.S165G | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV73721128; called by muse, mutect2, varscan2
- GANAB | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV60468884; called by muse, mutect2, varscan2
- GAR1 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as rs757617022, COSV56994108; called by muse, mutect2, varscan2
- GAS2L1 | c.1417del p.Q473Rfs*66 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs1215426760; called by mutect2, pindel, varscan2
- GAS2L1 | c.1839del p.P614Hfs*2 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | catalogued as rs78929040; called by mutect2, pindel
- GAS7 | c.539C>T p.T180M (on ENST00000432992 / NM_201433.2; = p.T40M on NM_003644.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs754573807, COSV60444264; called by mutect2, varscan2
- GATAD2A | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1324238340, COSV53076518; called by muse, mutect2
- GBX2 | c.525C>T p.V175= | Splice Region (SNP) | VAF 29/135 reads (21%) | catalogued as COSV60445874; called by muse, mutect2, varscan2
- GCN1 | c.7556C>T p.A2519V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs374035797; called by muse, mutect2, varscan2
- GCNT3 | c.1098G>A p.W366* | Nonsense Mutation (SNP) | VAF 28/145 reads (19%) | catalogued as COSV68532423; called by muse, mutect2, varscan2
- GDF6 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54628161; called by muse, mutect2, varscan2
- GDPD5 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs373413383, COSV61129088; called by muse, mutect2, varscan2
- GGN | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1340268034, COSV53059213; called by muse, mutect2
- GGT6 | c.1432G>A p.A478T (on ENST00000574154 / NM_001122890.3; = p.A446T on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs762142364, COSV54592825; called by mutect2, varscan2
- GIGYF1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781040173, COSV51939511; called by muse, mutect2, varscan2
- GIGYF1 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51947244; called by muse, mutect2, varscan2
- GIGYF2 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 52/211 reads (25%) | catalogued as COSV65247719; called by muse, mutect2, varscan2
- GIMAP1 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV56189722, COSV56190219; called by muse, mutect2, varscan2
- GINS3 | c.469T>A p.Y157N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); catalogued as COSV58920620; called by muse, mutect2, varscan2
- GLI2 | c.1747C>T p.R583C (on ENST00000361492 / NM_001374353.1; = p.R600C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs113407742; called by muse, mutect2, varscan2
- GLIS1 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs778490328, COSV56557419; called by muse, mutect2, varscan2
- GLRX | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV52987252; called by muse, mutect2, varscan2
- GMPS | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs762639569, COSV55812258; called by mutect2, varscan2
- GNAS | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs767104257, COSV58346861; called by muse, mutect2, varscan2
- GNG12 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV63974339; called by muse, mutect2, varscan2
- GNMT | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as COSV55105808; called by muse, mutect2, varscan2
- GNMT | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV55105815; called by muse, mutect2, varscan2
- GPAA1 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV60156615; called by muse, mutect2, varscan2
- GPAM | c.1802del p.G601Vfs*9 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | catalogued as rs1296236751; called by mutect2, pindel, varscan2
- GPATCH4 | c.629del p.K210Rfs*73 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | catalogued as rs754640631; called by mutect2, varscan2
- GPC6 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV100990247; called by muse, mutect2, varscan2
- GPKOW | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as COSV50245490, COSV50245705; called by muse, mutect2
- GPNMB | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV51701329; called by muse, mutect2, varscan2
- GPR1 | c.380del p.F127Sfs*2 | Frame Shift Del (DEL) | VAF 28/120 reads (23%) | catalogued as rs759796967; called by mutect2, pindel, varscan2
- GPR158 | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV66283937; called by muse, mutect2
- GPR17 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1345648384, COSV55757340; called by muse, mutect2, varscan2
- GPR179 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs750988170; called by muse, mutect2, varscan2
- GPR35 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs199596106, COSV60577189; called by muse, mutect2, varscan2
- GPR37L1 | c.1189C>A p.L397M | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66162858; called by muse, mutect2, varscan2
- GPSM3 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100901246, COSV66684205; called by muse, mutect2, varscan2
- GPT2 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.758); catalogued as rs1045338829, COSV60840389; called by muse, mutect2, varscan2
- GRB10 | c.1381G>A p.A461T (on ENST00000398812; = p.A415T on NM_001001549.3) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV60015419; called by muse, mutect2, varscan2
- GRIN1 | c.2684G>T p.R895M | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV59301255; called by muse, mutect2, varscan2
- GRIN2D | c.1105T>C p.W369R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as COSV99617136; called by muse, mutect2, varscan2
- GRIP1 | c.1577C>A p.A526D (on ENST00000359742 / NM_001379345.1; = p.A474D on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV54035194, COSV54045090; called by muse, varscan2
- GRK6 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62684493; called by muse, mutect2, varscan2
- GRM5 | c.1604C>T p.T535I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs780370059, COSV59632082; called by mutect2, varscan2
- GTF2H4 | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV52561424; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.393); catalogued as COSV100736489; called by mutect2, varscan2
- GTF3C1 | c.5474C>T p.A1825V | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs377528153, COSV62245335; called by muse, mutect2, varscan2
- GTF3C2 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 70/274 reads (26%) | catalogued as COSV53128967; called by muse, mutect2, varscan2
- GUCY2C | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV53796246; called by muse, mutect2, varscan2
- GUSB | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59224202; called by muse, mutect2, varscan2
- GUSB | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59221945, COSV59224210; called by muse, mutect2, varscan2
- GYG1 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.927); catalogued as COSV56051356; called by muse, mutect2
- H1-4 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV56802941, COSV56803752; called by muse, mutect2, varscan2
- HABP2 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as COSV63638161; called by muse, mutect2, varscan2
- HACD1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as rs150586011, COSV63516428; called by muse, varscan2
- HAL | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs375314208; called by muse, mutect2, varscan2
- HCFC1 | c.2723C>T p.T908M | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60078158; called by muse, mutect2
- HCFC1 | c.650A>G p.K217R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0.071); catalogued as COSV60078243; called by muse, mutect2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | catalogued as rs755844571, COSV63794110; called by mutect2, pindel, varscan2
- HEATR1 | c.5009C>T p.A1670V | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201522356, COSV63983326; called by muse, mutect2, varscan2
- HEATR5B | c.4571A>G p.Y1524C | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51859601; called by muse, mutect2, varscan2
- HECTD1 | c.3199C>T p.H1067Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as COSV67949414; called by muse, mutect2, varscan2
- HEPACAM2 | c.877A>G p.I293V (on ENST00000394468 / NM_001039372.4; = p.I281V on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.191); catalogued as rs1260097656, COSV59063756; called by muse, mutect2, varscan2
- HEPACAM2 | c.554del p.N185Mfs*25 (on ENST00000394468 / NM_001039372.4; = p.N173Mfs*25 on NM_198151.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as COSV59062549; called by mutect2, pindel, varscan2
- HERC2 | c.10711G>A p.A3571T | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.288); catalogued as rs370009597; called by muse, mutect2, varscan2
- HHATL | c.673T>G p.F225V | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60043250; called by muse, mutect2, varscan2
- HHIPL2 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58568198; called by muse, mutect2, varscan2
- HHLA2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.122); catalogued as rs752698352, COSV63320189; called by muse, mutect2, varscan2
- HID1 | c.892A>G p.S298G | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV59352409; called by muse, mutect2, varscan2
- HIF3A | c.1526C>A p.P509H (on ENST00000377670 / NM_152795.4; = p.P440H on NM_022462.4) | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV52205175, COSV99355625; called by muse, mutect2, varscan2
- HIVEP1 | c.1711T>C p.S571P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV101045923; called by muse, mutect2, varscan2
- HIVEP1 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192064941, COSV65105388; called by mutect2, varscan2
- HJURP | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64979668; called by muse, mutect2, varscan2
- HK1 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1275659810, COSV53864806; called by muse, mutect2, varscan2
- HLA-B | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV69522119, COSV69523175; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 48/78 reads (62%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPA2B1 | c.277C>T p.P93S (on ENST00000354667 / NM_031243.3; = p.P81S on NM_002137.4) | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV61161383; called by muse, mutect2, varscan2
- HNRNPF | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV61561070; called by muse, mutect2
- HNRNPH2 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV57267523; called by muse, mutect2, varscan2
- HOOK2 | c.1586del p.G529Afs*11 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | catalogued as rs768806444; called by mutect2, pindel, varscan2
- HOXA1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58029350; called by muse, mutect2, varscan2
- HOXA4 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as COSV57829178; called by muse, mutect2, varscan2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 28/118 reads (24%) | catalogued as rs770632206; called by pindel, varscan2
- HOXD9 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV50896251; called by muse, mutect2, varscan2
- HPS5 | c.1652G>A p.R551H (on ENST00000349215 / NM_181507.2; = p.R437H on NM_007216.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1037863397, COSV61688104; called by muse, mutect2, varscan2
- HR | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs942855695, COSV100455961, COSV57191191; called by muse, mutect2
- HRC | c.1397del p.P466Qfs*12 | Frame Shift Del (DEL) | VAF 31/127 reads (24%) | catalogued as COSV53255678; called by mutect2, pindel, varscan2
- HRH1 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs779665353, COSV67956054; called by muse, mutect2, varscan2
- HSD17B7 | c.680T>C p.L227S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV54419964; called by muse, mutect2, varscan2
- HSP90AB1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV62336472; called by muse, mutect2, varscan2
- HSPA4L | c.2446A>G p.T816A | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV56548945; called by muse, mutect2, varscan2
- HSPA5 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV61030072; called by muse, mutect2
- HSPB1 | c.438dup p.G147Rfs*14 | Frame Shift Ins (INS) | VAF 11/49 reads (22%) | catalogued as rs747325717; called by mutect2, pindel, varscan2
- HSPB3 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as rs776892769, COSV57357471; called by muse, mutect2, varscan2
- HSPG2 | c.10927G>A p.A3643T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201309996; called by muse, mutect2, varscan2
- HSPG2 | c.9539C>T p.A3180V | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs748710241, COSV65933465; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HTRA2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51215417; called by muse, mutect2, varscan2
- HYDIN | c.10441C>T p.R3481W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs76078590, COSV101154480; called by mutect2, varscan2
- ICAM5 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55749503; called by muse, varscan2
- ICAM5 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55747921; called by muse, varscan2
- ICAM5 | c.2033C>T p.T678M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV55749522; called by muse, mutect2
- ICMT | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.03); catalogued as COSV59474698; called by muse, mutect2
- IDE | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV56427790; called by muse, mutect2, varscan2
- IDUA | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as rs764394402, COSV56107079; called by muse, mutect2, varscan2
- IDUA | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56107098; called by muse, mutect2, varscan2
- IFI16 | c.1913G>A p.R638H (on ENST00000295809 / NM_001364867.2; = p.R582H on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.184); catalogued as rs758208458, COSV55533267; called by muse, mutect2, varscan2
- IFNA6 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV66506963; called by muse, mutect2, varscan2
- IFNLR1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1057242155, COSV59527737; called by muse, mutect2, varscan2
- IFT122 | c.2183A>G p.D728G (on ENST00000348417 / NM_052989.3; = p.D669G on NM_018262.4) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV56208906; called by muse, mutect2
- IGF2BP1 | c.175+2T>C p.X59_splice | Splice Site (SNP) | VAF 11/105 reads (10%) | catalogued as COSV51736603; called by muse, mutect2
- IGF2R | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV63628919; called by muse, mutect2, varscan2
- IGHV5-51 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371971064; called by muse, mutect2
- IGLON5 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54539144; called by muse, mutect2, varscan2
- IGLV1-51 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs551184530; called by muse, mutect2, varscan2
- IGSF1 | c.2489G>A p.S830N | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); catalogued as COSV63840702; called by muse, mutect2, varscan2
- IGSF1 | c.2193A>C p.R731S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.13); catalogued as COSV63840706; called by muse, mutect2, varscan2
- IGSF5 | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV66031579; called by muse, mutect2, varscan2
- IGSF8 | c.1240G>T p.G414W | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.884); catalogued as COSV58759261; called by muse, mutect2, varscan2
- IGSF9B | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV58073408; called by muse, mutect2, varscan2
- IKBKE | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.098); catalogued as COSV65625022; called by muse, mutect2
- IKZF1 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs375321410; called by mutect2, varscan2
- IKZF3 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs748446589, COSV53099754; called by muse, mutect2, varscan2
- IL12RB2 | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52027716; called by muse, varscan2
- IL16 | c.1055T>C p.I352T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV57268711; called by muse, mutect2, varscan2
- IL17B | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 90/167 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV55784391; called by muse, mutect2, varscan2
- IL17D | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59232028; called by muse, mutect2
- IL1R2 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374536258; called by muse, mutect2, varscan2
- IL4R | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.184); catalogued as COSV50180617; called by muse, mutect2, varscan2
- IL6R | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs764067079, COSV59819757; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- ILVBL | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373514197; called by muse, mutect2, varscan2
- INHBC | c.832G>T p.G278W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59006291; called by muse, mutect2, varscan2
- INTS1 | c.4570G>A p.V1524I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs771965212, COSV67179996; called by muse, mutect2, varscan2
- INTS1 | c.4301C>T p.P1434L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs965939725, COSV67180001; called by muse, mutect2, varscan2
- INTS2 | c.2608T>C p.C870R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV52157047; called by muse, mutect2
- IPO9 | c.1803G>T p.M601I | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64236445; called by muse, mutect2
- IPP | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63434165; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1151G>T p.S384I (on ENST00000485419 / NM_001197113.1; = p.S308I on NM_014575.3) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61861460; called by muse, mutect2, varscan2
- IRF3 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV55864762; called by muse, mutect2, varscan2
- IRF8 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV51900820; called by muse, mutect2, varscan2
- IRS2 | c.3629C>T p.A1210V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV65481017; called by muse, mutect2
1,953 further variants in this file (1,326 protein-altering or splice-affecting, 578 silent, 49 other) are not listed here.
